FM case AD16878 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors.
https://portal.gdc.cancer.gov/cases/430ee950-2d1b-4907-a42f-8c323ac8a9d0

Female, 80.4 years: Paraganglioma, NOS (ICD-O-3 8680/1); metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
